Somatic mutation profile of tumor specimen TCGA-UC-A7PF-01A (aliquot TCGA-UC-A7PF-01A-11D-A351-09) from TCGA case TCGA-UC-A7PF, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB1; Tumor grade: G2; Age at diagnosis: 44.9 years (16,412 days).
Specimen TCGA-UC-A7PF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 193ab405-488b-4aeb-895f-2b662e733234.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-UC-A7PF-11A (Solid Tissue Normal), aliquot TCGA-UC-A7PF-11A-31D-A351-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4746f5be-4bbe-4d38-a863-67583098663d

The open-access MAF lists 461 somatic variants for this specimen: 300 protein-altering or splice-affecting, 142 silent, 19 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 254, Silent 142, Nonsense Mutation 34, RNA 9, Splice Site 4, 5'UTR 3, Intron 3, 5'Flank 3, Frame Shift Del 2, In Frame Del 2, Splice Region 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VPS13B | c.6418C>T p.Q2140* | Nonsense Mutation (SNP) | VAF 9/27 reads (33%) | catalogued as rs1057516287, COSV62142755; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.3233C>T p.S1078F | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV70029871; called by muse, mutect2, varscan2
- ABHD15 | c.1406G>C p.*469Sext*28 | Nonstop Mutation (SNP) | VAF 7/23 reads (30%) | catalogued as COSV56195409; called by muse, mutect2, varscan2
- ABL1 | c.1223C>G p.P408R | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV59329860, COSV59332154; called by muse, mutect2, varscan2
- AC005324.2 | c.946G>A p.E316K | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.037); catalogued as rs746816242, COSV60886857; called by muse, mutect2, varscan2
- AC011462.1 | c.382G>C p.D128H | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.392); catalogued as rs1398036536, COSV54197248; called by muse, mutect2, varscan2
- AC024598.1 | c.1308C>G p.I436M | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.387); catalogued as COSV60823699, COSV60824103; called by muse, mutect2, varscan2
- ACIN1 | c.3907G>A p.D1303N | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.021); catalogued as COSV52976565; called by muse, mutect2, varscan2
- ACP4 | c.1130C>T p.S377F | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as COSV54516738, COSV54516942; called by muse, mutect2, varscan2
- ADAMTS1 | c.2282C>T p.S761F | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.652); catalogued as rs1164083613, COSV53170530; called by muse, mutect2, varscan2
- ADAMTS16 | c.157G>A p.G53S | Missense Mutation (SNP) | VAF 33/83 reads (40%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as rs781399042, COSV56990874; called by muse, mutect2, varscan2
- ADGRG6 | c.686C>G p.S229* | Nonsense Mutation (SNP) | VAF 8/27 reads (30%) | catalogued as COSV51592645; called by muse, mutect2, varscan2
- AKT1S1 | c.601C>T p.R201W (on ENST00000344175 / NM_001098633.4; = p.R221W on NM_032375.5) | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs374227857; called by muse, mutect2, varscan2
- ANKLE2 | c.2341G>A p.D781N | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT tolerated (0.41); PolyPhen benign (0.012); catalogued as COSV61709535; called by muse, mutect2, varscan2
- AP2A2 | c.2381C>G p.S794C | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV100173268, COSV59960487; called by muse, mutect2, varscan2
- ARHGAP35 | c.3235C>G p.Q1079E | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1405241007, COSV68331497; called by muse, mutect2, varscan2
- ARHGEF9 | c.157G>A p.E53K | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT tolerated (0.68); PolyPhen benign (0.017); catalogued as COSV53638558; called by muse, mutect2, varscan2
- ASAH2 | c.149C>T p.S50L | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as COSV61483434; called by muse, mutect2, varscan2
- ATP8B2 | c.1402G>A p.D468N (on ENST00000672630; = p.D435N on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.959); catalogued as rs181629150, COSV100527588; called by muse, mutect2, varscan2
- ATRN | c.3814C>T p.Q1272* | Nonsense Mutation (SNP) | VAF 13/52 reads (25%) | catalogued as COSV53528038; called by muse, mutect2, varscan2
- BAIAP2L1 | c.842C>T p.S281L | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as COSV50056128; called by muse, mutect2, varscan2
- BANK1 | c.1570G>A p.E524K | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.067); catalogued as COSV59843157; called by muse, mutect2, varscan2
- BCL9 | c.437C>G p.S146* | Nonsense Mutation (SNP) | VAF 18/62 reads (29%) | catalogued as COSV52342296, COSV52344465; called by muse, mutect2, varscan2
- BMP4 | c.313G>C p.E105Q | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.7); PolyPhen benign (0.015); catalogued as COSV55416081; called by muse, mutect2, varscan2
- BSN | c.4105G>A p.E1369K | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.024); catalogued as COSV56518715; called by muse, mutect2, varscan2
- CACNA1F | c.247C>T p.R83W | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.53); catalogued as rs782384281, COSV59904600, COSV59906497; called by muse, mutect2, varscan2
- CACNA1H | c.3334G>T p.D1112Y | Missense Mutation (SNP) | VAF 52/137 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs1297779114, COSV61991265; called by muse, mutect2, varscan2
- CAPN13 | c.788G>A p.R263K | Missense Mutation (SNP) | VAF 46/104 reads (44%) | SIFT tolerated (0.59); PolyPhen benign (0.035); catalogued as COSV54431153; called by muse, mutect2, varscan2
- CARMIL2 | c.3553G>C p.E1185Q | Missense Mutation (SNP) | VAF 31/127 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.575); catalogued as COSV54667804; called by muse, varscan2
- CARMIL2 | c.3688G>T p.E1230* | Nonsense Mutation (SNP) | VAF 40/136 reads (29%) | catalogued as COSV54665991, COSV54667818; called by muse, varscan2
- CATSPERD | c.364G>T p.E122* | Nonsense Mutation (SNP) | VAF 9/44 reads (20%) | catalogued as COSV67534863; called by muse, mutect2, varscan2
- CCDC160 | c.789G>A p.M263I | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.011); catalogued as rs1165763165, COSV66251642; called by muse, mutect2, varscan2
- CCDC73 | c.495G>C p.E165D | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58798853; called by muse, mutect2, varscan2
- CCNB3 | c.3144C>G p.F1048L | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT tolerated (0.32); PolyPhen benign (0.01); catalogued as rs1557214939, COSV52074040, COSV99329245; called by muse, mutect2, varscan2
- CCP110 | c.625G>A p.E209K | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.23); catalogued as COSV101195208; called by muse, mutect2, varscan2
- CDH20 | c.1798G>A p.D600N | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs1262191898, COSV53010227; called by muse, mutect2, varscan2
- CDHR1 | c.1399G>A p.D467N | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60562636; called by muse, mutect2, varscan2
- CDK12 | c.3969G>C p.L1323F (on ENST00000447079 / NM_016507.4; = p.L1314F on NM_015083.3) | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.034); catalogued as COSV70999760; called by muse, mutect2, varscan2
- CELSR3 | c.8929G>A p.D2977N | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.469); catalogued as COSV50862956; called by muse, mutect2, varscan2
- CEP170B | c.1789G>C p.E597Q (on ENST00000453495; = p.E526Q on NM_015005.3) | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.73); catalogued as COSV69024668; called by muse, mutect2, varscan2
- CEP85L | c.2413C>G p.Q805E | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV63823442; called by muse, mutect2, varscan2
- CERK | c.1604C>T p.S535L | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV53451352; called by muse, mutect2, varscan2
- CFAP46 | c.7286-1G>A p.X2429_splice | Splice Site (SNP) | VAF 6/16 reads (38%) | catalogued as COSV54149030; called by muse, mutect2, varscan2
- CFAP54 | c.5266C>G p.Q1756E | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.517); catalogued as COSV61572371; called by muse, mutect2, varscan2
- CFH | c.3107G>A p.R1036K | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.027); catalogued as COSV66408775; called by muse, mutect2, varscan2
- CHD3 | c.2281G>A p.D761N | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57875375; called by muse, mutect2, varscan2
- CIZ1 | c.1633G>A p.G545R | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751261139, COSV52971531; called by muse, mutect2, varscan2
- CLASP1 | c.2111C>T p.S704F | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT tolerated (0.43); PolyPhen benign (0.165); catalogued as COSV55324825; called by muse, mutect2, varscan2
- CLCN6 | c.652C>G p.Q218E | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.056); catalogued as COSV56740281; called by muse, mutect2, varscan2
- CLK2 | c.181G>A p.D61N | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV62877306; called by muse, mutect2, varscan2
- CMYA5 | c.4430C>T p.T1477I | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as rs1201488786, COSV71406123; called by muse, mutect2, varscan2
- CNTN5 | c.985G>A p.V329I | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as rs182344400; called by muse, mutect2, varscan2
- COL12A1 | c.43G>A p.A15T | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.052); catalogued as COSV59396550; called by muse, mutect2, varscan2
- COL18A1 | c.4162C>T p.Q1388* (on ENST00000359759 / NM_130444.3; = p.Q1153* on NM_030582.4) | Nonsense Mutation (SNP) | VAF 8/43 reads (19%) | catalogued as COSV60589062; called by muse, mutect2, varscan2
- COLGALT1 | c.1321G>A p.E441K | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.664); catalogued as COSV53109313; called by muse, mutect2, varscan2
- COQ5 | c.238G>A p.D80N | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56019104; called by muse, mutect2, varscan2
- COX10 | c.647C>G p.S216* | Nonsense Mutation (SNP) | VAF 3/25 reads (12%) | catalogued as COSV55405249; called by muse, mutect2
- CRLF1 | c.1061G>A p.R354Q | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.006); catalogued as rs745875637, COSV62260711; called by muse, mutect2, varscan2
- CTC1 | c.1736C>T p.S579F | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.01); catalogued as COSV59853395; called by muse, mutect2, varscan2
- CTNND1 | c.2170G>A p.E724K (on ENST00000399050 / NM_001085458.2; = p.E718K on NM_001331.3) | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.63); catalogued as COSV62383572; called by muse, mutect2, varscan2
- CTU1 | c.109G>A p.E37K | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.02); catalogued as rs1339728303, COSV70292420; called by muse, mutect2, varscan2
- DDI2 | c.1063G>A p.E355K | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100197831, COSV60779840; called by muse, mutect2, varscan2
- DDX18 | c.1696G>C p.E566Q | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.098); catalogued as COSV54306738; called by muse, mutect2, varscan2
- DENND1C | c.1262C>T p.S421F | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as COSV57568672; called by muse, mutect2, varscan2
- DGKK | c.2041G>A p.D681N | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV65707592; called by muse, mutect2, varscan2
- DHPS | c.147C>A p.F49L | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV52951591, COSV52951708, COSV52952106; called by muse, mutect2, varscan2
- DISP3 | c.2083G>T p.E695* | Nonsense Mutation (SNP) | VAF 15/43 reads (35%) | catalogued as rs752008451, COSV53828001; called by muse, mutect2, varscan2
- DMD | c.10369G>C p.D3457H | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58912462; called by muse, mutect2, varscan2
- DNAJC12 | c.358C>T p.H120Y | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56548443; called by muse, mutect2, varscan2
- DPY19L4 | c.85G>A p.E29K | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV68962935; called by muse, mutect2, varscan2
- DRP2 | c.703G>C p.E235Q | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.36); PolyPhen benign (0.076); catalogued as COSV100871757; called by muse, mutect2, varscan2
- DYDC2 | c.511C>T p.P171S | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs755351824, COSV55472389; called by muse, mutect2, varscan2
- DZIP3 | c.1082C>G p.S361C | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.894); catalogued as COSV64312159; called by muse, mutect2, varscan2
- ELK4 | c.182G>A p.R61Q | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56984966; called by muse, mutect2, varscan2
- ELL2 | c.292G>C p.D98H | Missense Mutation (SNP) | VAF 34/130 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV52982678; called by muse, mutect2, varscan2
- EPAS1 | c.37G>C p.E13Q | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55386729; called by muse, mutect2, varscan2
- ERCC6L2 | c.1530G>A p.M510I | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.468); catalogued as COSV56630575; called by muse, mutect2, varscan2
- FAM71D | c.874G>C p.E292Q | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV61295431, COSV61295610; called by muse, mutect2
- FARP1 | c.1204G>A p.E402K | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.79); PolyPhen benign (0.003); catalogued as COSV60337921; called by muse, mutect2, varscan2
- FGR | c.265G>A p.E89K | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.031); catalogued as COSV64969521; called by muse, mutect2, varscan2
- FHL1 | c.157-1G>A p.X53_splice | Splice Site (SNP) | VAF 8/29 reads (28%) | catalogued as COSV61781152; called by muse, mutect2, varscan2
- FKBPL | c.619G>T p.E207* | Nonsense Mutation (SNP) | VAF 7/28 reads (25%) | catalogued as COSV64322468; called by muse, mutect2, varscan2
- FKBPL | c.415G>A p.E139K | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.042); catalogued as COSV64322478, COSV64322665; called by muse, mutect2, varscan2
- FLG | c.5810C>G p.S1937C | Missense Mutation (SNP) | VAF 30/114 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); catalogued as rs777689005, COSV64242261, COSV64242695; called by muse, mutect2, varscan2
- FLT3 | c.1751C>G p.S584C | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.289); catalogued as COSV54048966, COSV99607092; called by muse, mutect2, varscan2
- FOXE1 | c.349G>C p.E117Q | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV64300423, COSV64300473; called by muse, mutect2, varscan2
- FYN | c.359G>T p.W120L | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as COSV57614531; called by muse, mutect2, varscan2
- GABRB1 | c.1255G>T p.D419Y | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.671); catalogued as COSV54982579; called by muse, mutect2, varscan2
- GCNA | c.1529C>G p.S510C | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as COSV65466851; called by muse, mutect2, varscan2
- GPR101 | c.1483G>A p.E495K | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.102); catalogued as COSV53238944; called by muse, mutect2, varscan2
- GPR50 | c.694G>A p.E232K | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.428); catalogued as COSV54439303; called by muse, mutect2, varscan2
- GRIN2A | c.2098T>A p.Y700N | Missense Mutation (SNP) | VAF 56/110 reads (51%) | SIFT deleterious (0.04); PolyPhen benign (0.088); catalogued as COSV58034273; called by muse, varscan2
- GRK4 | c.1662C>G p.F554L | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.83); PolyPhen benign (0.007); catalogued as COSV61669278; called by muse, mutect2, varscan2
- HEATR5B | c.5860G>A p.E1954K | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.206); catalogued as COSV51853043; called by muse, mutect2, varscan2
- HLA-C | c.493C>G p.Q165E | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.984); catalogued as CM1412141, COSV100880023, COSV100880581; called by muse, mutect2, varscan2
- HOXC5 | c.511G>C p.E171Q | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54536953; called by muse, mutect2, varscan2
- HPS6 | c.1193C>T p.S398L | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as COSV54625695; called by muse, mutect2, varscan2
- HSPA1L | c.1591G>C p.D531H | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV65150511; called by muse, mutect2, varscan2
- ICE1 | c.1358C>G p.S453C | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.785); catalogued as COSV56825579; called by muse, mutect2, varscan2
- IFI30 | c.721A>G p.T241A | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV69576575; called by muse, mutect2, varscan2
- IFT80 | c.2095G>T p.E699* | Nonsense Mutation (SNP) | VAF 9/44 reads (20%) | catalogued as COSV58447838; called by muse, mutect2, varscan2
- IGHG3 | c.20C>T p.S7L | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs761093846; called by muse, mutect2, varscan2
- IRF9 | c.277G>C p.E93Q | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV60703250; called by muse, mutect2, varscan2
- IRGQ | c.1039G>C p.E347Q | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as COSV60670718; called by muse, mutect2, varscan2
- ITFG1 | c.1423G>A p.D475N | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.964); catalogued as COSV57749115; called by muse, mutect2, varscan2
- KCNB2 | c.1719G>C p.E573D | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.999); catalogued as COSV73050392; called by muse, mutect2, varscan2
- KCNH4 | c.2665C>T p.R889C | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs1177535033, COSV52915698; called by muse, mutect2, varscan2
- KCTD20 | c.985G>C p.E329Q | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs754018529, COSV54803268; called by muse, mutect2, varscan2
- KCTD8 | c.230C>T p.S77F | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.637); catalogued as rs746687835, COSV63589461; called by muse, varscan2
- KDM5B | c.4160G>C p.R1387T | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV52508008; called by muse, mutect2, varscan2
- KIAA1549L | c.5234G>A p.G1745E (on ENST00000321505; = p.G2042E on NM_012194.3) | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.741); catalogued as COSV58589222; called by muse, mutect2, varscan2
- KIF13B | c.976A>C p.M326L | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV73054428; called by muse, mutect2, varscan2
- KIF1B | c.2569G>C p.D857H (on ENST00000377086 / NM_001365952.1; = p.D811H on NM_015074.3) | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (0.25); PolyPhen benign (0.251); catalogued as COSV55809161; called by muse, mutect2, varscan2
- KIFAP3 | c.142G>A p.E48K | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV63034111; called by muse, mutect2, varscan2
- KLHL36 | c.1569C>G p.C523W | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.958); catalogued as COSV50719180; called by muse, mutect2, varscan2
- KLHL4 | c.823C>T p.L275F | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.314); catalogued as rs928689740, COSV64138964; called by muse, mutect2, varscan2
- KMT2C | c.7261C>T p.Q2421* | Nonsense Mutation (SNP) | VAF 29/65 reads (45%) | catalogued as COSV100077379, COSV51442535; called by muse, mutect2, varscan2
- KMT2D | c.15130G>A p.D5044N | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV56442183; called by muse, mutect2, varscan2
- KMT2D | c.14917G>C p.D4973H | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.735); catalogued as COSV56442201; called by muse, mutect2, varscan2
- KMT2D | c.13672G>C p.E4558Q | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT tolerated (0.59); PolyPhen benign (0.109); catalogued as COSV56409205, COSV56442223; called by muse, mutect2, varscan2
- KMT2D | c.13429G>A p.G4477R | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.592); catalogued as COSV56442241, COSV99986636; called by muse, mutect2, varscan2
- L3MBTL4 | c.712G>A p.D238N | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs371583101; called by muse, mutect2, varscan2
- LAS1L | c.713C>T p.S238L | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV56707428; called by muse, mutect2, varscan2
- LDHAL6A | c.181G>A p.E61K | Missense Mutation (SNP) | VAF 37/114 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV55007813; called by muse, mutect2, varscan2
- LEPR | c.1304C>T p.S435L | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.038); catalogued as COSV60755837; called by muse, mutect2, varscan2
- LPIN2 | c.842C>G p.S281C | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.285); catalogued as COSV55239910; called by muse, mutect2, varscan2
- LRRC8D | c.1492G>A p.E498K | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV61579443; called by muse, varscan2
- MAP3K19 | c.3787G>A p.G1263R | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100208778, COSV59639079; called by muse, mutect2, varscan2
- MAPK9 | c.373C>T p.H125Y | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV58122049; called by muse, mutect2, varscan2
- MAST3 | c.2764C>T p.P922S | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.259); catalogued as COSV53220925; called by muse, varscan2
- MATK | c.1101G>C p.K367N (on ENST00000310132 / NM_139355.3; = p.K368N on NM_002378.4) | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59554709; called by muse, mutect2, varscan2
- MBTD1 | c.637G>C p.E213Q | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.808); catalogued as COSV64503399; called by muse, mutect2, varscan2
- MFSD5 | c.166G>C p.D56H | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV61565589; called by muse, mutect2, varscan2
- MMRN2 | c.1250C>T p.S417F | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.107); catalogued as COSV64400793; called by muse, varscan2
- MMS22L | c.883G>T p.E295* | Nonsense Mutation (SNP) | VAF 11/42 reads (26%) | catalogued as COSV51516926; called by muse, mutect2, varscan2
- MN1 | c.3841C>G p.L1281V | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV56558467; called by muse, mutect2, varscan2
- MOCS1 | c.173C>T p.S58F | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV57936512; called by muse, mutect2, varscan2
- MTR | c.1649A>C p.H550P | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1351941930, COSV63965005; called by muse, mutect2, varscan2
- MUC16 | c.11879C>G p.S3960C | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV67468307; called by muse, mutect2, varscan2
- MUCL3 | c.1480G>A p.G494S (on ENST00000304311; = p.G1370S on NM_080870.4) | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.915); catalogued as rs1359473609, COSV58517428; called by muse, mutect2, varscan2
- MYH15 | c.3139G>A p.E1047K | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV56305778, COSV56310713, COSV99842969; called by muse, mutect2, varscan2
- MYO5A | c.3598G>A p.E1200K | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.046); catalogued as COSV62560329; called by muse, mutect2, varscan2
- NCAN | c.1835C>T p.S612L | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs754950280, COSV53051608; called by muse, mutect2, varscan2
- NDUFV1 | c.225G>A p.W75* | Nonsense Mutation (SNP) | VAF 13/58 reads (22%) | catalogued as COSV59595605; called by muse, mutect2, varscan2
- NEB | c.2227C>T p.H743Y | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV51419240; called by muse, mutect2, varscan2
- NEDD4 | c.2152G>A p.E718K (on ENST00000508342 / NM_001284338.1; = p.E299K on NM_006154.4) | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.146); catalogued as COSV59062029; called by muse, mutect2, varscan2
- NEXMIF | c.3577C>T p.Q1193* | Nonsense Mutation (SNP) | VAF 18/109 reads (17%) | catalogued as COSV50032797; called by muse, mutect2, varscan2
- NHLRC3 | c.187_189del p.T63del | In Frame Del (DEL) | VAF 18/67 reads (27%) | catalogued as rs1321576580; called by pindel, varscan2
- NIPBL | c.776G>C p.G259A | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.067); catalogued as COSV56951855; called by muse, mutect2, varscan2
- NKD2 | c.695G>A p.R232Q | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (0.61); PolyPhen benign (0.019); catalogued as rs762371758, COSV56891861; called by muse, mutect2, varscan2
- NLGN1 | c.1052G>C p.R351P | Missense Mutation (SNP) | VAF 51/105 reads (49%) | SIFT tolerated (0.23); PolyPhen benign (0.019); catalogued as COSV64333161, COSV64334421; called by muse, mutect2, varscan2
- NLRP13 | c.368A>G p.E123G | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV61621961; called by muse, mutect2, varscan2
- NPAS4 | c.985G>A p.E329K | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV100215043, COSV60650639; called by muse, mutect2, varscan2
- NPAT | c.1507G>C p.D503H | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.551); catalogued as rs780092429, COSV53718194; called by muse, mutect2, varscan2
- NRXN1 | c.4311G>C p.E1437D | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV100640265, COSV60499979; called by muse, mutect2, varscan2
- OPA1 | c.178C>T p.Q60* | Nonsense Mutation (SNP) | VAF 28/102 reads (27%) | catalogued as COSV62480765; called by muse, mutect2, varscan2
- OPA1 | c.1056G>C p.Q352H (on ENST00000361510 / NM_130837.3; = p.Q297H on NM_015560.3) | Missense Mutation (SNP) | VAF 32/178 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62480775, COSV62484068; called by muse, mutect2, varscan2
- OR2M2 | c.156C>A p.D52E | Missense Mutation (SNP) | VAF 31/138 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.226); catalogued as COSV62898415, COSV62899111; called by muse, mutect2, varscan2
- OR3A3 | c.716C>G p.S239C | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52167543; called by muse, mutect2, varscan2
- OR51F2 | c.698C>T p.S233L | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.05); catalogued as COSV59064842; called by muse, mutect2, varscan2
- OR5P3 | c.686A>G p.H229R | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs139657716; called by muse, mutect2, varscan2
- PAK1 | c.1532C>T p.S511L | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as COSV53696691, COSV53700439; called by muse, mutect2, varscan2
- PAN3 | c.926C>G p.S309* | Nonsense Mutation (SNP) | VAF 12/68 reads (18%) | catalogued as COSV66706996, COSV66708727; called by muse, mutect2, varscan2
- PANK1 | c.88G>C p.E30Q | Missense Mutation (SNP) | VAF 6/8 reads (75%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.272); catalogued as COSV56808279; called by muse, mutect2, varscan2
- PCDH15 | c.5083G>C p.E1695Q | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.184); catalogued as rs1305240743, COSV57315355; called by muse, mutect2, varscan2
- PCDH19 | c.868C>T p.Q290* | Nonsense Mutation (SNP) | VAF 12/51 reads (24%) | catalogued as COSV55263535; called by muse, mutect2, varscan2
- PCDHB12 | c.917C>G p.P306R | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.158); catalogued as COSV53396886; called by muse, mutect2, varscan2
- PCLO | c.9169G>A p.G3057R | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61636911; called by muse, mutect2, varscan2
- PCNT | c.6514G>C p.D2172H | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.399); catalogued as COSV64028494; called by muse, mutect2, varscan2
- PCNX4 | c.592G>A p.E198K | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58304340; called by muse, mutect2, varscan2
- PGM2L1 | c.184T>C p.C62R | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT tolerated (0.21); PolyPhen benign (0.157); catalogued as COSV53346987; called by muse, mutect2, varscan2
- PHF2 | c.1249G>C p.E417Q | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.489); catalogued as COSV63681111; called by muse, mutect2, varscan2
- PIKFYVE | c.38C>T p.S13F | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0.172); catalogued as COSV52241588; called by muse, mutect2, varscan2
- PITPNM3 | c.2166G>C p.Q722H | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (1); PolyPhen probably damaging (0.956); catalogued as rs368515060; called by muse, mutect2, varscan2
- PLA2G12B | c.565G>C p.E189Q | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.958); catalogued as COSV61826206; called by muse, mutect2, varscan2
- PLCB4 | c.150G>A p.W50* | Nonsense Mutation (SNP) | VAF 5/81 reads (6%) | catalogued as COSV99593992; called by muse, mutect2
- PLCE1 | c.4255G>C p.E1419Q | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53351823; called by muse, mutect2, varscan2
- PLEKHH3 | c.1172C>T p.S391L | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV52217737; called by muse, mutect2, varscan2
- PLK3 | c.512C>T p.S171F | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as COSV59499875; called by muse, mutect2, varscan2
- PNPLA6 | c.2404G>C p.E802Q (on ENST00000414982 / NM_001166111.2; = p.E754Q on NM_006702.5) | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV55378680; called by muse, mutect2
- POGZ | c.1969C>T p.L657F | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV55033634; called by muse, mutect2, varscan2
- POT1 | c.973G>A p.E325K | Missense Mutation (SNP) | VAF 9/96 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs1554421987, COSV62930921, COSV62935186; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PPP1R12B | c.937G>C p.E313Q | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.109); catalogued as COSV61117359; called by muse, mutect2, varscan2
- PPP1R26 | c.977G>A p.R326H | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated (0.24); PolyPhen benign (0.013); catalogued as rs761538566, COSV63354986; called by muse, mutect2, varscan2
- PRDM7 | c.1157G>T p.G386V | Missense Mutation (SNP) | VAF 10/107 reads (9%) | SIFT tolerated, low confidence (0.6); PolyPhen probably damaging (0.988); catalogued as COSV100371015; called by muse, mutect2, varscan2
- PRKCA | c.916G>A p.E306K | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.014); catalogued as rs1355720093, COSV52585132; called by muse, mutect2, varscan2
- PRL | c.187G>C p.E63Q | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.172); catalogued as COSV60592173; called by muse, mutect2, varscan2
- PROP1 | c.608C>T p.A203V | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV57645007; called by muse, mutect2, varscan2
- PRSS23 | c.938C>T p.P313L | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV54706934; called by muse, mutect2, varscan2
- PTX3 | c.52G>A p.E18K | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.265); catalogued as COSV55821673; called by muse, mutect2, varscan2
- RAB11FIP1 | c.1288G>A p.E430K | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54760280; called by muse, mutect2, varscan2
- RABEP2 | c.254C>T p.S85L | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100707060, COSV62869538; called by muse, mutect2, varscan2
- RASSF2 | c.581G>A p.R194H | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs369276882, COSV65081772; called by muse, mutect2, varscan2
- RC3H2 | c.3185C>T p.S1062L | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.354); catalogued as COSV100605265; called by muse, mutect2, varscan2
- RGL1 | c.1124G>A p.R375Q (on ENST00000360851 / NM_001297672.2; = p.R410Q on NM_015149.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100486479, COSV58985942; called by muse, mutect2, varscan2
- RIBC1 | c.1111C>T p.H371Y | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs782152990, COSV51448076; called by muse, mutect2, varscan2
- RIF1 | c.890G>A p.W297* | Nonsense Mutation (SNP) | VAF 15/64 reads (23%) | catalogued as COSV54617368; called by muse, mutect2, varscan2
- RNF111 | c.910G>C p.E304Q | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs763521728, COSV62086267; called by muse, mutect2, varscan2
- RNF121 | c.730G>C p.E244Q | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs757824081, COSV52621098; called by muse, mutect2, varscan2
- RP2 | c.874C>A p.L292M | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.468); catalogued as COSV54462122; called by muse, mutect2, varscan2
- RP9 | c.319C>A p.R107S | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as COSV51806933; called by muse, mutect2, varscan2
- RRM1 | c.979G>T p.D327Y | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV56164305; called by muse, mutect2, varscan2
- RTEL1 | c.1919G>T p.G640V | Missense Mutation (SNP) | VAF 28/108 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as rs1262230406, COSV100541591, COSV58894344; called by muse, mutect2, varscan2
- RTL5 | c.1697G>A p.R566Q | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.184); catalogued as rs1462526303, COSV65453562; called by muse, mutect2
- RTRAF | c.120C>G p.Y40* | Nonsense Mutation (SNP) | VAF 16/47 reads (34%) | catalogued as COSV55563244; called by muse, mutect2
- RTTN | c.1046C>G p.S349C | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.988); catalogued as rs1406683396, COSV55345143, COSV55350371; called by muse, mutect2, varscan2
- RYR3 | c.12377C>T p.A4126V (on ENST00000389232; = p.A4127V on NM_001036.6) | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.116); catalogued as rs749374315, COSV66786898; called by muse, mutect2, varscan2
- SACS | c.10115C>T p.S3372L | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (0.28); PolyPhen benign (0.194); catalogued as COSV66540283; called by muse, mutect2, varscan2
- SAFB | c.2573G>C p.G858A | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs755838374, COSV52651492; called by muse, mutect2, varscan2
- SAGE1 | c.809C>T p.S270L | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); catalogued as COSV61013723; called by muse, mutect2, varscan2
- SAMD9 | c.2658G>A p.M886I | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.127); catalogued as COSV66075400; called by muse, mutect2, varscan2
- SBNO2 | c.1345G>C p.E449Q | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.816); catalogued as COSV62320047; called by muse, mutect2, varscan2
- SCAF11 | c.1328C>T p.S443F | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.456); catalogued as COSV65476699; called by muse, mutect2, varscan2
- SEC31A | c.3488C>T p.S1163L (on ENST00000355196 / NM_001318120.1; = p.S1124L on NM_016211.4) | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52345917; called by muse, mutect2, varscan2
- SELL | c.530C>G p.S177* (on ENST00000650983; = p.S164* on NM_000655.5) | Nonsense Mutation (SNP) | VAF 12/52 reads (23%) | catalogued as COSV52552037; called by muse, mutect2, varscan2
- SERPIND1 | c.514G>C p.E172Q | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.52); PolyPhen benign (0.012); catalogued as COSV53138750; called by muse, mutect2, varscan2
- SETX | c.1520C>G p.S507* | Nonsense Mutation (SNP) | VAF 9/29 reads (31%) | catalogued as COSV56385924; called by muse, mutect2, varscan2
- SHKBP1 | c.1437C>G p.I479M | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV52540086; called by muse, mutect2, varscan2
- SIGLEC12 | c.1405+1G>T p.X469_splice (on ENST00000291707 / NM_053003.4; = p.X351_splice on NM_033329.2) | Splice Site (SNP) | VAF 24/96 reads (25%) | catalogued as rs374180089, COSV52461780; called by muse, mutect2, varscan2
- SLC22A6 | c.1438G>A p.E480K | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); catalogued as rs1230203789, COSV64560269; called by mutect2, varscan2
- SLC25A13 | c.871G>A p.E291K | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.058); catalogued as COSV55707546; called by muse, mutect2, varscan2
- SLC29A4 | c.1478C>G p.S493* | Nonsense Mutation (SNP) | VAF 12/49 reads (24%) | catalogued as COSV51874403; called by muse, mutect2, varscan2
- SLC4A3 | c.415G>A p.E139K | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT tolerated (0.2); PolyPhen benign (0.142); catalogued as COSV56094035; called by muse, mutect2, varscan2
- SLC4A5 | c.1423G>A p.D475N | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.501); catalogued as COSV61027912; called by muse, mutect2
- SLCO2A1 | c.1437G>C p.M479I | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.72); PolyPhen benign (0.001); catalogued as COSV60486098; called by muse, mutect2, varscan2
- SND1 | c.112C>G p.Q38E | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.222); catalogued as COSV61241273; called by muse, mutect2, varscan2
- SNRPA1 | c.233G>A p.R78H | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.279); catalogued as rs776784734, COSV54257502; called by muse, mutect2, varscan2
- SOHLH1 | c.245A>T p.Q82L | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.308); catalogued as COSV53681736; called by muse, mutect2, varscan2
- SPEN | c.10666G>A p.E3556K | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV65269750; called by muse, mutect2, varscan2
- SPINT1 | c.1552G>A p.E518K (on ENST00000344051 / NM_181642.3; = p.E502K on NM_003710.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV59801963; called by muse, mutect2
- SPP1 | c.175-1G>C p.X59_splice | Splice Site (SNP) | VAF 12/47 reads (26%) | catalogued as COSV52951876; called by muse, mutect2, varscan2
- SREBF2 | c.859C>T p.Q287* | Nonsense Mutation (SNP) | VAF 17/49 reads (35%) | catalogued as COSV63331320; called by muse, mutect2, varscan2
- SYNE1 | c.19273G>C p.D6425H (on ENST00000367255 / NM_182961.4; = p.D6354H on NM_033071.3) | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.668); catalogued as COSV54988771; called by muse, mutect2, varscan2
- SYNE2 | c.17509C>T p.L5837F | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1567555408, COSV59951771; called by muse, mutect2, varscan2
- SYT14 | c.10G>C p.E4Q | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.003); catalogued as COSV65413051; called by muse, mutect2, varscan2
- TAF1L | c.3403C>G p.Q1135E | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.017); catalogued as COSV54261735, COSV54264219; called by muse, mutect2, varscan2
- TENM1 | c.5011G>T p.V1671F | Missense Mutation (SNP) | VAF 8/123 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV100948849; called by muse, mutect2
- TEX15 | c.4954G>C p.E1652Q (on ENST00000256246; = p.E2035Q on NM_001350162.2) | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV56346941; called by muse, mutect2, varscan2
- TFPI | c.889G>A p.E297K | Missense Mutation (SNP) | VAF 33/70 reads (47%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.709); catalogued as rs781414695, COSV51901138; called by muse, mutect2, varscan2
- TFPI2 | c.233C>A p.T78N | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.958); catalogued as COSV55990713; called by muse, mutect2, varscan2
- TGFB1I1 | c.661C>T p.P221S (on ENST00000394863 / NM_001042454.3; = p.P204S on NM_015927.4) | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated (0.51); PolyPhen benign (0.014); catalogued as COSV62358011; called by muse, mutect2, varscan2
- TKTL1 | c.13G>A p.E5K | Missense Mutation (SNP) | VAF 35/171 reads (20%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); catalogued as COSV54213098; called by muse, mutect2, varscan2
- TLR3 | c.1216C>T p.H406Y | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs1320040002, COSV57168741; called by muse, mutect2, varscan2
- TMBIM4 | c.25C>T p.P9S | Missense Mutation (SNP) | VAF 34/186 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as rs1271530556, COSV53969037; called by muse, mutect2, varscan2
- TMC8 | c.306C>G p.F102L | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV59209742, COSV59211455; called by muse, mutect2, varscan2
- TMC8 | c.942C>G p.I314M | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.896); catalogued as COSV59209749; called by muse, mutect2, varscan2
- TMEM184B | c.340G>A p.V114I | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT tolerated (0.81); PolyPhen benign (0.021); catalogued as rs201541960, COSV62674496; called by muse, mutect2, varscan2
- TMEM44 | c.757C>T p.R253W (on ENST00000392432 / NM_001166305.2; = p.R206W on NM_138399.5) | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.073); catalogued as rs1304939192, COSV56449173; called by muse, mutect2, varscan2
- TMEM74 | c.266G>A p.G89E | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV52463402, COSV52464240; called by muse, mutect2, varscan2
- TMPRSS15 | c.1741G>C p.E581Q | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53040412; called by muse, mutect2, varscan2
- TMPRSS6 | c.1211G>A p.R404H | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs771131901, COSV60978555; called by muse, mutect2, varscan2
- TNIK | c.2104C>T p.Q702* | Nonsense Mutation (SNP) | VAF 59/156 reads (38%) | catalogued as COSV52683113; called by muse, mutect2, varscan2
- TNS4 | c.670C>T p.R224* | Nonsense Mutation (SNP) | VAF 8/44 reads (18%) | catalogued as rs761851227, COSV54185156; called by muse, mutect2, varscan2
- TP53BP1 | c.316C>G p.Q106E | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.777); catalogued as COSV55501947, COSV55503619; called by muse, mutect2, varscan2
- TRIP12 | c.2775T>C p.G925= | Splice Region (SNP) | VAF 7/19 reads (37%) | catalogued as COSV52264242; called by muse, mutect2, varscan2
- TRO | c.2155A>G p.T719A | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV99435626; called by muse, mutect2
- TRPC7 | c.2038G>C p.E680Q | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.54); catalogued as COSV61458139; called by muse, mutect2, varscan2
- TTN | c.73345G>A p.D24449N (on ENST00000591111; = p.D17025N on NM_003319.4) | Missense Mutation (SNP) | VAF 13/57 reads (23%) | PolyPhen probably damaging (0.975); catalogued as rs1197356544, COSV60081923; called by muse, mutect2, varscan2
- TUT7 | c.310G>C p.D104H | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.92); catalogued as COSV52895834; called by muse, mutect2, varscan2
- UBASH3B | c.1930G>C p.E644Q | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT tolerated (0.14); PolyPhen benign (0.086); catalogued as COSV52495183; called by muse, mutect2, varscan2
- UFL1 | c.1507G>C p.E503Q | Missense Mutation (SNP) | VAF 21/102 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.1); catalogued as COSV65149901; called by muse, mutect2, varscan2
- UNC13C | c.2126C>T p.S709L | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.026); catalogued as COSV52875589; called by muse, mutect2, varscan2
- UNC13C | c.2219C>T p.S740F | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.07); catalogued as COSV52851008, COSV52875609; called by muse, mutect2, varscan2
- UNC45A | c.418C>T p.Q140* | Nonsense Mutation (SNP) | VAF 11/42 reads (26%) | catalogued as COSV57746032; called by muse, mutect2, varscan2
- USP15 | c.2899G>C p.D967H (on ENST00000280377 / NM_001351159.2; = p.D938H on NM_006313.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.243); catalogued as COSV54792446; called by muse, mutect2, varscan2
- USP51 | c.964C>T p.Q322* | Nonsense Mutation (SNP) | VAF 7/24 reads (29%) | catalogued as COSV72351667; called by muse, mutect2, varscan2
- VAV1 | c.937C>T p.Q313* | Nonsense Mutation (SNP) | VAF 7/44 reads (16%) | catalogued as COSV58384058; called by muse, mutect2, varscan2
- VCPIP1 | c.1354G>C p.E452Q | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.35); PolyPhen benign (0.193); catalogued as COSV60047396; called by muse, mutect2, varscan2
- WASF2 | c.468C>G p.F156L | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV71005610; called by muse, mutect2, varscan2
- WASL | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 28/128 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.006); catalogued as COSV56133804; called by muse, varscan2
- WDFY2 | c.347G>C p.R116T | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as rs770989218, COSV53289578; called by muse, mutect2, varscan2
- WDR11 | c.3125C>T p.S1042L | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs771733026, COSV54788647; called by muse, mutect2, varscan2
- WDR27 | c.1745C>T p.S582L | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.744); catalogued as COSV61209245; called by muse, mutect2, varscan2
- WFS1 | c.184G>A p.E62K | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV56989163; called by muse, mutect2, varscan2
- WNK3 | c.2455C>T p.H819Y | Missense Mutation (SNP) | VAF 33/112 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.335); catalogued as COSV63614185; called by muse, mutect2, varscan2
- WWOX | c.944G>A p.G315E | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs530883793, COSV68354564; called by muse, mutect2, varscan2
- ZCCHC8 | c.1214C>G p.S405C | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV60318368; called by muse, mutect2, varscan2
- ZFHX3 | c.7552C>T p.Q2518* | Nonsense Mutation (SNP) | VAF 4/23 reads (17%) | catalogued as COSV51719482; called by muse, mutect2, varscan2
- ZFHX4 | c.7015G>A p.E2339K | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV50838972; called by muse, mutect2, varscan2
- ZMPSTE24 | c.17C>A p.S6* | Nonsense Mutation (SNP) | VAF 7/36 reads (19%) | catalogued as COSV65639406, COSV65640266; called by muse, mutect2, varscan2
- ZNF14 | c.1816G>A p.E606K | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.742); catalogued as rs1182907340, COSV59849688; called by muse, mutect2, varscan2
- ZNF185 | c.1157G>T p.R386M | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.742); catalogued as COSV59276045, COSV59277851; called by muse, mutect2, varscan2
- ZNF350 | c.841C>T p.Q281* | Nonsense Mutation (SNP) | VAF 11/55 reads (20%) | catalogued as COSV54708912; called by muse, mutect2, varscan2
- ZNF350 | c.340C>T p.H114Y | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.363); catalogued as COSV54708921, COSV54710834; called by muse, mutect2, varscan2
- ZNF439 | c.697G>T p.E233* | Nonsense Mutation (SNP) | VAF 31/110 reads (28%) | catalogued as COSV58309634, COSV58310734; called by muse, mutect2, varscan2
- ZNF483 | c.649G>A p.E217K | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.027); catalogued as COSV58515719; called by muse, mutect2, varscan2
- ZNF493 | c.326C>T p.S109F | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as COSV62750064; called by muse, mutect2, varscan2
- ZNF521 | c.1387C>G p.Q463E | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs763858130, COSV64127005, COSV64127209; called by muse, mutect2, varscan2
- ZNF761 | c.425C>T p.S142L | Missense Mutation (SNP) | VAF 17/110 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV61888433; called by muse, mutect2, varscan2
- ZNF781 | c.128G>C p.R43T | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.52); PolyPhen benign (0.225); catalogued as COSV62201450; called by muse, mutect2, varscan2
- ZNF81 | c.692C>A p.S231Y | Missense Mutation (SNP) | VAF 35/174 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as rs781785337, COSV58576405, COSV58577116; called by muse, mutect2, varscan2
- ZYG11B | c.557C>G p.P186R | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53753245; called by muse, mutect2, varscan2
- ACACA | c.278C>T p.S93L | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ANKRD36B | c.2216C>T p.S739L | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- FGD1 | c.980_991del p.P327_G331delinsR | In Frame Del (DEL) | VAF 10/62 reads (16%) | called by mutect2, pindel, varscan2
- TAF15 | c.1752A>T p.R584S (on ENST00000605844 / NM_139215.3; = p.R581S on NM_003487.4) | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- TRAV8-2 | c.28G>C p.E10Q | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated (0.61); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TRIM28 | c.1010_1016dup p.K340Dfs*19 | Frame Shift Ins (INS) | VAF 6/46 reads (13%) | called by mutect2, varscan2
- VRTN | c.966del p.D322Efs*53 | Frame Shift Del (DEL) | VAF 13/59 reads (22%) | called by mutect2, pindel, varscan2
- WWC2 | c.2802del p.M935* | Frame Shift Del (DEL) | VAF 18/61 reads (30%) | called by mutect2, pindel, varscan2
- ABCA7 | c.3381G>A p.L1127= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as rs1382049825, COSV54030010; called by muse, mutect2, varscan2
- ABCB1 | c.1137G>A p.S379= | Silent (SNP) | VAF 21/63 reads (33%) | catalogued as rs200370991, COSV55951158; called by muse, mutect2, varscan2
- ABCB5 | c.2526G>C p.L842= (on ENST00000404938 / NM_001163941.2; = p.L397= on NM_178559.6) | Silent (SNP) | VAF 18/63 reads (29%) | catalogued as rs767448281, COSV51706992; called by muse, mutect2, varscan2
- ABCC9 | c.3279C>T p.L1093= | Silent (SNP) | VAF 11/66 reads (17%) | catalogued as rs758097449, COSV53972788; called by muse, mutect2, varscan2
- ABCG5 | c.1317G>A p.V439= | Silent (SNP) | VAF 23/62 reads (37%) | catalogued as COSV53210974; called by muse, mutect2, varscan2
- ADAD2 | c.1080C>T p.L360= (on ENST00000315906 / NM_001145400.2; = p.L442= on NM_139174.4) | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as rs1288181751, COSV51893509; called by muse, mutect2
- ADAMTS12 | c.2289G>A p.G763= | Silent (SNP) | VAF 18/44 reads (41%) | catalogued as COSV61263543; called by muse, mutect2, varscan2
- AFDN | c.4566G>A p.E1522= | Silent (SNP) | VAF 7/33 reads (21%) | catalogued as COSV100652340; called by muse, mutect2, varscan2
- ALPK3 | c.831C>T p.N277= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as rs1381829636, COSV51933768; called by muse, mutect2
- ALS2 | c.2721G>A p.L907= | Silent (SNP) | VAF 24/46 reads (52%) | catalogued as COSV99968600; called by muse, mutect2, varscan2
- APEX1 | c.768C>G p.L256= | Silent (SNP) | VAF 11/41 reads (27%) | catalogued as COSV51657753; called by muse, mutect2, varscan2
- APOC1 | c.180T>C p.L60= | Silent (SNP) | VAF 7/50 reads (14%) | catalogued as COSV52991662; called by muse, mutect2, varscan2
- ARID1A | c.2799G>A p.G933= | Silent (SNP) | VAF 20/83 reads (24%) | catalogued as rs374337987, COSV61378146; called by muse, mutect2, varscan2
- ATP1A2 | c.2037C>G p.L679= | Silent (SNP) | VAF 4/19 reads (21%) | catalogued as COSV100767587; called by muse, mutect2, varscan2
- AWAT2 | c.417C>T p.L139= | Silent (SNP) | VAF 15/79 reads (19%) | catalogued as rs1291272722, COSV52142613, COSV99339513; called by muse, mutect2, varscan2
- BAMBI | c.549G>T p.L183= | Silent (SNP) | VAF 3/32 reads (9%) | catalogued as COSV65003055; called by muse, mutect2
- BCR | c.2916G>A p.L972= | Silent (SNP) | VAF 17/51 reads (33%) | catalogued as COSV59931538; called by muse, mutect2, varscan2
- BIN2 | c.867G>A p.E289= | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as COSV57205495, COSV57205789; called by muse, mutect2, varscan2
- CAPRIN2 | c.1314C>T p.S438= | Silent (SNP) | VAF 13/38 reads (34%) | catalogued as COSV51832693; called by muse, mutect2, varscan2
- CASP8AP2 | c.3276G>A p.V1092= | Silent (SNP) | VAF 17/59 reads (29%) | catalogued as rs768627572, COSV52747159; called by muse, mutect2, varscan2
- CASP8AP2 | c.3576G>A p.L1192= | Silent (SNP) | VAF 5/27 reads (19%) | catalogued as rs754987878, COSV52747165; called by muse, mutect2, varscan2
- CDH11 | c.2253G>A p.V751= | Silent (SNP) | VAF 5/25 reads (20%) | catalogued as COSV51762664; called by muse, mutect2
- CDK6 | c.195G>A p.L65= | Silent (SNP) | VAF 5/18 reads (28%) | catalogued as COSV56008319; called by muse, mutect2, varscan2
- CDKL5 | c.2958C>T p.F986= | Silent (SNP) | VAF 7/60 reads (12%) | catalogued as rs765366935, COSV66105922; called by muse, mutect2, varscan2
- CENPBD1 | c.279G>A p.L93= | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as rs760826828, COSV51919270; called by mutect2, varscan2
- CHD5 | c.3429G>A p.V1143= | Silent (SNP) | VAF 7/30 reads (23%) | catalogued as COSV99312165; called by muse, mutect2, varscan2
- CLP1 | c.198C>T p.F66= | Silent (SNP) | VAF 17/49 reads (35%) | catalogued as rs267603020, COSV57054502; called by muse, mutect2, varscan2
- CMKLR1 | c.702C>T p.L234= (on ENST00000312143 / NM_001142344.2; = p.L232= on NM_004072.3) | Silent (SNP) | VAF 12/32 reads (38%) | catalogued as COSV56438479; called by muse, mutect2, varscan2
- CMTR2 | c.87C>T p.L29= | Silent (SNP) | VAF 17/61 reads (28%) | catalogued as COSV57603493; called by muse, mutect2, varscan2
- COL18A1 | c.438G>A p.E146= | Silent (SNP) | VAF 16/63 reads (25%) | catalogued as COSV62702022; called by muse, mutect2, varscan2
- COL24A1 | c.498T>C p.F166= | Silent (SNP) | VAF 4/40 reads (10%) | catalogued as COSV65306764; called by muse, mutect2
- COL6A3 | c.1107G>A p.L369= | Silent (SNP) | VAF 14/33 reads (42%) | catalogued as COSV55090475; called by muse, mutect2, varscan2
- COLEC12 | c.1215G>A p.L405= | Silent (SNP) | VAF 25/73 reads (34%) | catalogued as COSV68370765; called by muse, mutect2, varscan2
- CPS1 | c.1827C>T p.L609= | Silent (SNP) | VAF 10/22 reads (45%) | catalogued as COSV51810984; called by muse, mutect2, varscan2
- CUBN | c.5982G>A p.P1994= | Silent (SNP) | VAF 9/19 reads (47%) | catalogued as rs560009723, COSV64716353, COSV64727785; called by muse, mutect2, varscan2
- CYC1 | c.591C>G p.L197= | Silent (SNP) | VAF 7/30 reads (23%) | catalogued as COSV59644417; called by muse, mutect2, varscan2
- DCAF4L2 | c.1125C>T p.F375= | Silent (SNP) | VAF 11/52 reads (21%) | catalogued as COSV60478930; called by muse, mutect2, varscan2
- DCAF8L1 | c.1248C>T p.L416= | Silent (SNP) | VAF 16/75 reads (21%) | catalogued as COSV71595303; called by muse, mutect2, varscan2
- DHFR2 | c.153G>A p.V51= | Silent (SNP) | VAF 16/132 reads (12%) | catalogued as COSV58935552; called by muse, mutect2, varscan2
- DNAJC14 | c.1746C>T p.L582= | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as rs1466799892, COSV99670612; called by muse, mutect2, varscan2
- DOT1L | c.2550G>C p.L850= | Silent (SNP) | VAF 23/121 reads (19%) | catalogued as COSV101288490; called by muse, mutect2, varscan2
- ECI1 | c.249G>A p.E83= | Silent (SNP) | VAF 24/120 reads (20%) | catalogued as COSV100066420; called by muse, mutect2, varscan2
- ELL | c.528G>A p.R176= | Silent (SNP) | VAF 12/60 reads (20%) | catalogued as COSV53212781; called by muse, mutect2, varscan2
- ESRRG | c.366G>A p.S122= | Silent (SNP) | VAF 26/70 reads (37%) | catalogued as rs771693345, COSV63161713; called by muse, mutect2, varscan2
- FKBPL | c.618G>A p.K206= | Silent (SNP) | VAF 7/28 reads (25%) | catalogued as COSV64322472; called by muse, mutect2, varscan2
- FXR1 | c.1551G>A p.L517= | Silent (SNP) | VAF 13/97 reads (13%) | catalogued as COSV59763135; called by muse, mutect2, varscan2
- GABRA1 | c.19C>T p.L7= | Silent (SNP) | VAF 6/41 reads (15%) | catalogued as COSV50105144; called by muse, mutect2, varscan2
- GJB3 | c.570C>T p.F190= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as rs1307706793, COSV64904612; called by muse, mutect2
- GNAT2 | c.645C>T p.F215= | Silent (SNP) | VAF 7/42 reads (17%) | catalogued as rs534677249, COSV63554960; called by muse, mutect2, varscan2
- GPR137 | c.660G>A p.A220= | Silent (SNP) | VAF 9/27 reads (33%) | catalogued as rs745531080, COSV57402235; called by muse, mutect2, varscan2
- GPRIN3 | c.1761G>A p.K587= | Silent (SNP) | VAF 18/51 reads (35%) | catalogued as COSV60885035; called by muse, mutect2, varscan2
- GRIN2A | c.2160G>A p.L720= | Silent (SNP) | VAF 45/116 reads (39%) | catalogued as COSV58034261; called by muse, varscan2
- GSTA5 | c.552G>A p.L184= | Silent (SNP) | VAF 28/103 reads (27%) | catalogued as rs567319452, COSV52862261; called by muse, mutect2, varscan2
- H4C6 | c.198G>C p.V66= | Silent (SNP) | VAF 10/33 reads (30%) | catalogued as rs760722568, COSV66685476, COSV66685716; called by muse, mutect2, varscan2
- HLA-DMB | c.228C>G p.L76= | Silent (SNP) | VAF 17/88 reads (19%) | catalogued as COSV66870774; called by muse, mutect2, varscan2
- HLA-DMB | c.120C>T p.F40= | Silent (SNP) | VAF 13/61 reads (21%) | catalogued as COSV66870777; called by muse, mutect2, varscan2
- HSPA6 | c.1356C>G p.T452= | Silent (SNP) | VAF 21/104 reads (20%) | catalogued as COSV59061146; called by muse, mutect2, varscan2
- IFNA21 | c.141C>T p.I47= | Silent (SNP) | VAF 35/148 reads (24%) | catalogued as COSV66518472; called by muse, mutect2, varscan2
- INTS7 | c.2481G>A p.L827= | Silent (SNP) | VAF 16/44 reads (36%) | catalogued as COSV65344352; called by muse, mutect2, varscan2
- KIF26B | c.4326G>A p.L1442= | Silent (SNP) | VAF 13/45 reads (29%) | catalogued as COSV63642037; called by muse, mutect2, varscan2
- KIF2C | c.2034C>G p.T678= | Silent (SNP) | VAF 11/57 reads (19%) | catalogued as COSV64764565; called by muse, mutect2, varscan2
- KIF4B | c.406C>T p.L136= | Silent (SNP) | VAF 13/69 reads (19%) | catalogued as COSV70528048, COSV70529434; called by muse, mutect2, varscan2
- KLHL38 | c.1554G>A p.V518= | Silent (SNP) | VAF 16/57 reads (28%) | catalogued as COSV58087505; called by muse, mutect2, varscan2
- KRTAP10-3 | c.129G>A p.L43= | Silent (SNP) | VAF 13/54 reads (24%) | catalogued as rs1322735457, COSV59963381; called by muse, mutect2, varscan2
- LIMCH1 | c.3099C>G p.L1033= | Silent (SNP) | VAF 17/50 reads (34%) | catalogued as COSV100573279; called by muse, mutect2, varscan2
- LRG1 | c.354G>C p.L118= | Silent (SNP) | VAF 10/46 reads (22%) | catalogued as COSV56703895; called by muse, mutect2, varscan2
- MAGED1 | c.1785G>A p.V595= | Silent (SNP) | VAF 19/76 reads (25%) | catalogued as COSV58515314; called by muse, mutect2, varscan2
- MAP4 | c.459C>A p.V153= | Silent (SNP) | VAF 11/36 reads (31%) | catalogued as COSV64240217; called by muse, mutect2, varscan2
- MAP4K1 | c.979C>T p.L327= | Silent (SNP) | VAF 3/17 reads (18%) | catalogued as COSV67710507; called by muse, mutect2
- MARCO | c.1122G>A p.V374= | Silent (SNP) | VAF 27/70 reads (39%) | catalogued as COSV59054666; called by muse, mutect2, varscan2
- MICB | c.756G>A p.Q252= | Silent (SNP) | VAF 24/97 reads (25%) | catalogued as COSV52856650; called by muse, mutect2, varscan2
- MIER2 | c.1561C>T p.L521= | Silent (SNP) | VAF 28/122 reads (23%) | catalogued as COSV53395937; called by muse, mutect2, varscan2
- MOB2 | c.300C>T p.V100= | Silent (SNP) | VAF 16/55 reads (29%) | catalogued as COSV57318605; called by muse, mutect2, varscan2
- MROH2B | c.4599C>T p.L1533= | Silent (SNP) | VAF 17/51 reads (33%) | catalogued as rs373077636, COSV68184552; called by muse, mutect2, varscan2
- MTOR | c.5916C>T p.L1972= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as COSV63871889, COSV63876649; called by mutect2, varscan2
- MUC16 | c.873C>T p.L291= | Silent (SNP) | VAF 6/37 reads (16%) | catalogued as rs1348664190, COSV67468312, COSV67495897; called by mutect2, varscan2
- MXRA7 | c.516G>A p.Q172= | Silent (SNP) | VAF 12/38 reads (32%) | catalogued as COSV63321344; called by muse, mutect2, varscan2
- MYH8 | c.4257G>A p.K1419= | Silent (SNP) | VAF 10/48 reads (21%) | catalogued as COSV67965579; called by muse, mutect2, varscan2
- NID2 | c.2892C>T p.D964= | Silent (SNP) | VAF 17/43 reads (40%) | catalogued as rs142814187; called by muse, mutect2, varscan2
- NLRP11 | c.504G>A p.L168= | Silent (SNP) | VAF 13/57 reads (23%) | catalogued as COSV64087479; called by muse, mutect2, varscan2
- NMT1 | c.1002G>A p.K334= | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as COSV51959837; called by muse, mutect2, varscan2
- NPAS4 | c.345G>A p.Q115= | Silent (SNP) | VAF 9/33 reads (27%) | catalogued as COSV60650628; called by muse, mutect2, varscan2
- NPC1 | c.2550C>T p.I850= | Silent (SNP) | VAF 22/56 reads (39%) | catalogued as rs542171272, COSV99340690; called by muse, mutect2, varscan2
- NPHS1 | c.1359G>A p.Q453= | Silent (SNP) | VAF 29/115 reads (25%) | catalogued as COSV62287997; called by muse, mutect2, varscan2
- NRK | c.270C>T p.L90= | Silent (SNP) | VAF 8/43 reads (19%) | catalogued as COSV54597221; called by muse, mutect2, varscan2
- NTRK2 | c.2016C>T p.F672= (on ENST00000323115 / NM_001369534.1; = p.F688= on NM_006180.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 12/55 reads (22%) | catalogued as rs764069110, COSV52854905; called by muse, mutect2, varscan2
- NUAK1 | c.1575G>A p.L525= | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as COSV54603549; called by muse, mutect2, varscan2
- OGN | c.681C>A p.S227= | Silent (SNP) | VAF 26/123 reads (21%) | catalogued as COSV52760748, COSV52761010; called by muse, mutect2, varscan2
- PABPC5 | c.397C>T p.L133= | Silent (SNP) | VAF 18/95 reads (19%) | catalogued as COSV57040983; called by muse, mutect2, varscan2
- PAX1 | c.1384C>A p.R462= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as COSV68271980; called by muse, mutect2, varscan2
- PDZD7 | c.879G>T p.R293= | Silent (SNP) | VAF 35/108 reads (32%) | catalogued as COSV64646299; called by muse, mutect2, varscan2
- PER1 | c.1413C>T p.F471= | Silent (SNP) | VAF 22/81 reads (27%) | catalogued as rs1034967004, COSV57919602; called by muse, mutect2, varscan2
- PER1 | c.1275C>T p.I425= | Silent (SNP) | VAF 17/50 reads (34%) | catalogued as COSV57919608; called by muse, mutect2, varscan2
- PMFBP1 | c.126C>T p.D42= | Silent (SNP) | VAF 10/33 reads (30%) | catalogued as COSV52824640; called by muse, mutect2, varscan2
- PRAMEF19 | c.1119G>A p.L373= | Silent (SNP) | VAF 72/280 reads (26%) | called by muse, mutect2, varscan2
- PRND | c.396C>G p.L132= | Silent (SNP) | VAF 17/68 reads (25%) | catalogued as COSV59896583; called by muse, mutect2, varscan2
- PRSS1 | c.96G>A p.E32= | Silent (SNP) | VAF 10/52 reads (19%) | called by muse, mutect2
- PTPN13 | c.1326C>T p.S442= | Silent (SNP) | VAF 4/21 reads (19%) | catalogued as COSV100365604, COSV57408161; called by muse, mutect2
- PTX4 | c.1203C>T p.L401= (on ENST00000447419 / NM_001328608.2; = p.L396= on NM_001013658.1) | Silent (SNP) | VAF 12/84 reads (14%) | catalogued as rs372576163; called by muse, mutect2, varscan2
- R3HDM4 | c.675C>T p.V225= | Silent (SNP) | VAF 19/42 reads (45%) | catalogued as COSV64293160; called by muse, mutect2, varscan2
- RAB5C | c.393C>T p.L131= | Silent (SNP) | VAF 22/63 reads (35%) | catalogued as rs567674506, COSV100651367; called by muse, mutect2, varscan2
- RIC8B | c.210C>T p.L70= | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as rs765635957, COSV62694652; called by muse, mutect2
- RNF220 | c.1485G>C p.L495= | Silent (SNP) | VAF 8/37 reads (22%) | catalogued as COSV59190527; called by muse, mutect2, varscan2
- RYR1 | c.4743C>T p.S1581= | Silent (SNP) | VAF 7/35 reads (20%) | catalogued as rs370041876; called by muse, mutect2, varscan2
- SAG | c.300C>T p.A100= | Silent (SNP) | VAF 21/35 reads (60%) | catalogued as rs781781373, COSV68591147; called by muse, mutect2, varscan2
- SASS6 | c.1539G>C p.L513= | Silent (SNP) | VAF 17/68 reads (25%) | catalogued as COSV54928071; called by muse, mutect2, varscan2
- SCAF8 | c.429C>T p.V143= | Silent (SNP) | VAF 13/48 reads (27%) | catalogued as COSV65791859; called by muse, mutect2, varscan2
- SCN4A | c.4323C>T p.F1441= | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as rs372442108; called by muse, mutect2, varscan2
- SCNN1A | c.2009G>A p.*670= | Silent (SNP) | VAF 18/41 reads (44%) | catalogued as rs758737621, COSV57435757; called by muse, mutect2, varscan2
- SCNN1B | c.615C>T p.F205= | Silent (SNP) | VAF 11/53 reads (21%) | catalogued as COSV56304689; called by muse, mutect2, varscan2
- SIPA1L1 | c.4242C>T p.F1414= | Silent (SNP) | VAF 10/42 reads (24%) | catalogued as COSV62170375; called by muse, mutect2, varscan2
- SIPA1L3 | c.2358C>T p.F786= | Silent (SNP) | VAF 15/59 reads (25%) | catalogued as COSV55914662; called by muse, mutect2, varscan2
- SIRPG | c.1017C>T p.V339= | Silent (SNP) | VAF 27/90 reads (30%) | catalogued as COSV53806888, COSV53807595; called by muse, mutect2
- SLC12A1 | c.1650C>T p.L550= | Silent (SNP) | VAF 14/58 reads (24%) | catalogued as COSV66795131; called by muse, mutect2, varscan2
- SLC20A2 | c.1107G>A p.E369= | Silent (SNP) | VAF 15/73 reads (21%) | catalogued as COSV60603790; called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.2194T>C p.L732= (on ENST00000540229 / NM_001371097.1; = p.L671= on NM_001009562.4) | Silent (SNP) | VAF 11/61 reads (18%) | catalogued as COSV101044619, COSV67444086; called by muse, mutect2, varscan2
- SPR | c.675G>A p.L225= | Silent (SNP) | VAF 18/83 reads (22%) | catalogued as COSV52297908; called by muse, mutect2, varscan2
- ST3GAL3 | c.861C>T p.L287= (on ENST00000361392 / NM_174964.4; = p.L272= on NM_006279.5) | Silent (SNP) | VAF 15/45 reads (33%) | catalogued as COSV53514276; called by muse, mutect2, varscan2
- SYNE2 | c.20415G>T p.V6805= | Silent (SNP) | VAF 25/84 reads (30%) | catalogued as COSV59945121, COSV59951780; called by muse, mutect2, varscan2
- TCF19 | c.546C>T p.L182= | Silent (SNP) | VAF 46/154 reads (30%) | catalogued as rs1308295226, COSV52562787, COSV52563712; called by muse, mutect2, varscan2
- TEKT2 | c.90G>A p.L30= | Silent (SNP) | VAF 9/31 reads (29%) | catalogued as COSV52881011; called by muse, mutect2, varscan2
- TFDP3 | c.1188C>T p.D396= | Silent (SNP) | VAF 11/64 reads (17%) | catalogued as rs183061934, COSV100033169; called by muse, mutect2, varscan2
- TNFRSF10D | c.27G>A p.P9= | Silent (SNP) | VAF 17/34 reads (50%) | catalogued as COSV57035811; called by muse, mutect2, varscan2
- TNKS1BP1 | c.3084C>T p.F1028= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as COSV64101143; called by mutect2, varscan2
- TWNK | c.1986G>A p.Q662= | Silent (SNP) | VAF 13/52 reads (25%) | catalogued as COSV61326928; called by muse, mutect2, varscan2
- UBC | c.1866C>A p.T622= | Silent (SNP) | VAF 21/76 reads (28%) | catalogued as COSV60059577, COSV60060720; called by muse, mutect2, varscan2
- UBE4A | c.1476C>T p.I492= (on ENST00000252108 / NM_001204077.2; = p.I499= on NM_004788.4) | Silent (SNP) | VAF 35/75 reads (47%) | catalogued as COSV52804306; called by muse, mutect2, varscan2
- UNC13A | c.2292C>T p.F764= | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as COSV53196519; called by muse, mutect2, varscan2
- VPS33B | c.903G>A p.L301= | Silent (SNP) | VAF 9/31 reads (29%) | catalogued as COSV60980224; called by muse, mutect2, varscan2
- VPS8 | c.2466G>A p.E822= (on ENST00000625842 / NM_001349294.1; = p.E820= on NM_015303.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 21/112 reads (19%) | catalogued as COSV54979755, COSV54986300; called by muse, mutect2, varscan2
- WIPF1 | c.1023C>G p.L341= | Silent (SNP) | VAF 31/69 reads (45%) | catalogued as COSV55814900; called by muse, mutect2, varscan2
- WRNIP1 | c.1332G>A p.L444= | Silent (SNP) | VAF 29/71 reads (41%) | catalogued as COSV66356084; called by muse, mutect2, varscan2
- ZAN | c.8067C>T p.F2689= | Silent (SNP) | VAF 9/35 reads (26%) | catalogued as COSV100769027; called by muse, varscan2
- ZBBX | c.9A>G p.R3= | Silent (SNP) | VAF 28/169 reads (17%) | catalogued as COSV56789999; called by muse, mutect2, varscan2
- ZBED9 | c.3327C>T p.F1109= | Silent (SNP) | VAF 6/31 reads (19%) | catalogued as COSV71729430; called by muse, mutect2, varscan2
- ZBP1 | c.87G>A p.V29= | Silent (SNP) | VAF 11/26 reads (42%) | catalogued as rs1486348219, COSV59061946; called by muse, mutect2, varscan2
- ZMYM3 | c.3912C>T p.L1304= | Silent (SNP) | VAF 10/82 reads (12%) | catalogued as COSV100077452, COSV58737970; called by muse, mutect2, varscan2
- ZNF71 | c.1257C>T p.F419= | Silent (SNP) | VAF 15/76 reads (20%) | catalogued as COSV60147962; called by muse, mutect2, varscan2
- ZNF75D | c.294G>A p.L98= | Silent (SNP) | VAF 14/57 reads (25%) | catalogued as COSV66132768; called by muse, mutect2, varscan2
- ZNF782 | c.174C>T p.F58= | Silent (SNP) | VAF 8/35 reads (23%) | catalogued as COSV100001074; called by muse, mutect2, varscan2
- ZNF81 | c.1329C>T p.I443= | Silent (SNP) | VAF 18/67 reads (27%) | catalogued as COSV58576416; called by muse, mutect2, varscan2
- ZSWIM3 | c.1353G>A p.L451= | Silent (SNP) | VAF 10/22 reads (45%) | catalogued as COSV54847702; called by muse, mutect2, varscan2
- AC024940.1 | n.2563C>G | RNA (SNP) | VAF 20/119 reads (17%) | called by muse, mutect2, varscan2
- AC024940.1 | n.2168C>T | RNA (SNP) | VAF 32/181 reads (18%) | called by muse, mutect2, varscan2
- AL132655.6 | chr20:58840113 C>T | 5'Flank (SNP) | VAF 35/85 reads (41%) | catalogued as rs202131370, COSV58335675; called by muse, mutect2, varscan2
- AL353804.4 | chrX:73823911 G>A | 5'Flank (SNP) | VAF 14/43 reads (33%) | catalogued as rs763383305; called by muse, mutect2, varscan2
- AL353804.7 | chrX:73852289 G>A | 3'Flank (SNP) | VAF 60/264 reads (23%) | called by muse, mutect2, varscan2
- ATP6AP1L | n.1908C>T | RNA (SNP) | VAF 6/36 reads (17%) | catalogued as rs775409129, COSV66474545; called by muse, mutect2, varscan2
- BSG | c.-1C>A | 5'UTR (SNP) | VAF 21/133 reads (16%) | catalogued as COSV61077020; called by muse, mutect2, varscan2
- C9orf106 | n.212C>T | RNA (SNP) | VAF 10/47 reads (21%) | called by muse, mutect2, varscan2
- CORT | c.-11C>T | 5'UTR (SNP) | VAF 14/49 reads (29%) | catalogued as COSV57630648; called by muse, mutect2, varscan2
- EPB41L4B | c.1409+1944G>A | Intron (SNP) | VAF 16/48 reads (33%) | catalogued as COSV65797017; called by muse, mutect2, varscan2
- HERC2P3 | n.1298G>A | RNA (SNP) | VAF 26/398 reads (7%) | called by muse, mutect2
- HERC2P3 | n.512G>A | RNA (SNP) | VAF 26/332 reads (8%) | catalogued as rs533190589; called by muse, mutect2
- IP6K2 | c.202+940G>C | Intron (SNP) | VAF 16/59 reads (27%) | catalogued as COSV60793861; called by muse, mutect2, varscan2
- MAP3K20 | c.987+4230G>A | Intron (SNP) | VAF 7/33 reads (21%) | catalogued as COSV59103379; called by muse, mutect2, varscan2
- OR2W5 | n.612C>G | RNA (SNP) | VAF 4/19 reads (21%) | called by muse, mutect2, varscan2
- SNORD93 | n.40C>T | RNA (SNP) | VAF 69/182 reads (38%) | called by muse, mutect2, varscan2
- UBXN4 | c.-1G>A | 5'UTR (SNP) | VAF 6/17 reads (35%) | catalogued as rs1290454309, COSV99738568, COSV99738834; called by muse, mutect2, varscan2
- XIST | n.8360C>T | RNA (SNP) | VAF 18/74 reads (24%) | called by muse, mutect2, varscan2
- ZNF578 | chr19:52451401 C>T | 5'Flank (SNP) | VAF 11/35 reads (31%) | catalogued as COSV56517445; called by muse, mutect2, varscan2
